Somatic mutation profile of tumor specimen TCGA-ZF-AA5N-01A (aliquot TCGA-ZF-AA5N-01A-11D-A42E-08) from TCGA case TCGA-ZF-AA5N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 62.3 years (22,741 days).
Specimen TCGA-ZF-AA5N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8faab6f-1f1b-45fb-9b11-d585765ccbf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA5N-10A (Blood Derived Normal), aliquot TCGA-ZF-AA5N-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/356bc7b9-863c-443e-85a3-450bfc487af4

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 5, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- ACSM2B | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as rs745852481, COSV61657708; called by muse, mutect2, varscan2
- AHDC1 | c.1619C>A p.P540H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899292; called by muse, mutect2
- AL121899.2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV67349533; called by muse, mutect2, varscan2
- ARID1A | c.1515_1518del p.Q505Hfs*113 | Frame Shift Del (DEL) | VAF 103/146 reads (71%) | catalogued as COSV61370598; called by mutect2, pindel, varscan2
- ARID1B | c.6120del p.H2041Tfs*45 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | catalogued as COSV51647124; called by mutect2, pindel, varscan2
- ASXL2 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55452762; called by muse, mutect2, varscan2
- AUNIP | c.132_135del p.K45Lfs*58 | Frame Shift Del (DEL) | VAF 40/60 reads (67%) | catalogued as rs1200449724; called by pindel, varscan2
- BIRC6 | c.9640C>T p.L3214F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101428289; called by muse, mutect2
- C1S | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377093428; called by muse, mutect2
- C6orf118 | c.1197A>G p.I399M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758980537, COSV57812168; called by muse, mutect2, varscan2
- CILP2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1454704597, COSV52272188; called by muse, mutect2, varscan2
- CWC27 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66883796; called by muse, mutect2, varscan2
- DAPK2 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56043441; called by muse, mutect2, varscan2
- DDX52 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1308713871; called by mutect2, varscan2
- ECI2 | c.658A>C p.N220H (on ENST00000380118 / NM_206836.3; = p.N190H on NM_006117.2) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV60984754; called by muse, mutect2, varscan2
- ELAC1 | c.165T>G p.I55M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53996133; called by muse, varscan2
- HCAR2 | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV100186503; called by muse, mutect2, varscan2
- LRFN5 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53241351; called by muse, mutect2, varscan2
- M1AP | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as rs1191151446, COSV51842437; called by muse, mutect2, varscan2
- MORF4L1 | c.133C>G p.H45D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1234435748, COSV58703699; called by muse, mutect2, varscan2
- NKRF | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs757800855, COSV58660497; called by muse, mutect2, varscan2
- NUP98 | c.4073T>G p.L1358R (on ENST00000359171 / NM_001365126.1; = p.L1341R on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61428021; called by muse, mutect2, varscan2
- P2RX7 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV55853073; called by muse, mutect2, varscan2
- PARD3B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs368769074; called by muse, mutect2, varscan2
- PHF24 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753629419, COSV54272847; called by muse, mutect2, varscan2
- PPIP5K2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58602130; called by muse, mutect2, varscan2
- PRRC2C | c.3023A>C p.N1008T (on ENST00000367742; = p.N1006T on NM_015172.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV58900325; called by muse, mutect2, varscan2
- RBM12B | c.2647C>T p.R883C | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs748400099, COSV67897136; called by muse, mutect2, varscan2
- RHOA | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.097); catalogued as COSV69041535, COSV69043016; called by muse, mutect2, varscan2
- RPS6KA3 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65386715; called by muse, mutect2, varscan2
- SART3 | c.2944T>C p.*982Rext*63 (on ENST00000228284; = p.*964Rext*63 on NM_014706.4) | Nonstop Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99934069; called by muse, mutect2, varscan2
- SEPTIN9 | c.334A>C p.I112L (on ENST00000427177 / NM_001113491.2; = p.I94L on NM_006640.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61201805; called by muse, mutect2, varscan2
- SERINC4 | c.619T>G p.W207G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762293704, COSV51048556; called by muse, varscan2
- SIRPB1 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs770087762, COSV53537208; called by muse, mutect2, varscan2
- STAG1 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV52600439; called by muse, mutect2
- TECRL | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV67085262; called by muse, mutect2, varscan2
- TENM1 | c.5404G>C p.D1802H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1323505163, COSV64424190; called by muse, mutect2, varscan2
- TET1 | c.5339G>A p.R1780Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.697); catalogued as rs557747751, COSV101017722, COSV65381633; called by muse, mutect2, varscan2
- TRRAP | c.3601G>A p.G1201R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV62838031; called by muse, mutect2, varscan2
- TTN | c.8078T>C p.V2693A (on ENST00000591111; = p.V2647A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | PolyPhen possibly damaging (0.654); catalogued as rs780868304, COSV59865425; called by muse, mutect2, varscan2
- ZNF292 | c.2154G>C p.Q718H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60535128; called by muse, mutect2, varscan2
- ZNF493 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62749028; called by muse, mutect2, varscan2
- ELF3 | c.720del p.K241Sfs*13 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by pindel, varscan2
- FAT1 | c.8440_8461del p.Y2814Tfs*8 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- MVD | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- ZFP36L1 | c.597_598dup p.H200Rfs*34 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.2274G>A p.P758= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs144684061; called by muse, mutect2, varscan2
- CD163 | c.1941G>A p.R647= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV63129026; called by muse, mutect2, varscan2
- CSN1S1 | c.489G>A p.P163= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs764905619, COSV55889596; called by muse, mutect2, varscan2
- ELMOD2 | c.354G>A p.R118= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100062886; called by muse, mutect2
- GCNA | c.615C>T p.S205= | Silent (SNP) | VAF 196/466 reads (42%) | catalogued as COSV65465690; called by muse, varscan2
- HEPH | c.2637C>T p.S879= (on ENST00000343002; = p.S612= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs748396986, COSV57958462; called by muse, mutect2, varscan2
- IBSP | c.516C>T p.N172= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs752731584, COSV56894484; called by muse, mutect2, varscan2
- PI16 | c.1191C>T p.S397= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV65319518; called by muse, mutect2, varscan2
- RESF1 | c.3705A>G p.V1235= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV57019343; called by muse, mutect2
- STKLD1 | c.756G>A p.L252= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV64311637; called by muse, mutect2, varscan2
- TFIP11 | c.324C>T p.D108= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs760598435, COSV68020223; called by muse, mutect2, varscan2
- NOXRED1 | c.682+65T>G | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53627396; called by muse, mutect2
